Somatic mutation profile of cancer-model specimen HCM-CSHL-0653-C18-85O (3D Organoid, passage 5; aliquot HCM-CSHL-0653-C18-85O-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0653-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.9 years (20,789 days).
Specimen HCM-CSHL-0653-C18-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fe3f7cc-993b-4afb-9c7b-30c7dec18af4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0653-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0653-C18-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a78bbd-7137-4913-a9a8-db9f2a5d4f6a

The open-access MAF lists 140 somatic variants for this specimen: 97 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 37, Nonsense Mutation 10, Intron 4, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 1, 5'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 337/339 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.1651C>A p.P551T | Missense Mutation (SNP) | VAF 51/1250 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.23); catalogued as COSV57875505; called by muse, mutect2
- ANKRD7 | c.15C>A p.F5L | Missense Mutation (SNP) | VAF 168/249 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV54554138; called by muse, mutect2, varscan2
- ATRX | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 65/218 reads (30%) | catalogued as CM081520, COSV64869650; called by muse, mutect2, varscan2
- CFH | c.3643C>T p.R1215* | Nonsense Mutation (SNP) | VAF 191/427 reads (45%) | catalogued as rs121913051, CM010324, CM134087, COSV66413637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CILP2 | c.2897G>A p.R966H | Missense Mutation (SNP) | VAF 38/1038 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.238); catalogued as rs1344989823; called by muse, mutect2
- CNTNAP2 | c.1211G>T p.W404L | Missense Mutation (SNP) | VAF 123/669 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV62270779; called by muse, mutect2, varscan2
- COL16A1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs200464413; called by muse, mutect2
- COL5A1 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 367/682 reads (54%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.623); catalogued as COSV65673617; called by muse, mutect2, varscan2
- DOCK9 | c.4948C>T p.R1650W (on ENST00000376460 / NM_001366676.2; = p.R1651W on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/841 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371892069; called by muse, mutect2, varscan2
- DYSF | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 297/710 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs886043941, COSV50325367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT3 | c.7288G>T p.E2430* | Nonsense Mutation (SNP) | VAF 116/440 reads (26%) | catalogued as COSV53130236; called by muse, mutect2, varscan2
- FAT4 | c.5372C>A p.P1791Q | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100630436; called by muse, mutect2
- FKBP15 | c.3637G>A p.D1213N | Missense Mutation (SNP) | VAF 172/383 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.685); catalogued as rs754073510; called by muse, varscan2
- GRID1 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 482/749 reads (64%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.712); catalogued as rs368060520; called by muse, mutect2, varscan2
- GTF3C2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 181/426 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53125713; called by muse, mutect2, varscan2
- INHBA | c.737A>C p.Q246P | Missense Mutation (SNP) | VAF 144/656 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.808); catalogued as COSV54224270; called by muse, varscan2
- KCNJ1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 247/653 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773713405, COSV60662790; called by muse, mutect2, varscan2
- MICU3 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs374645079; called by muse, mutect2, varscan2
- MOG | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 346/521 reads (66%) | catalogued as rs767614040, COSV65320989; called by muse, mutect2, varscan2
- OBSL1 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 65/652 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs763001564; called by muse, mutect2, varscan2
- OR8B8 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV60143936; called by muse, mutect2, varscan2
- PDE1B | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs200096201; called by muse, mutect2, varscan2
- PXDNL | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.389); catalogued as rs757076660, COSV62480016; called by muse, mutect2, varscan2
- RIPK2 | c.397A>C p.N133H | Missense Mutation (SNP) | VAF 199/367 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99609670; called by muse, mutect2, varscan2
- RYR2 | c.14360A>G p.N4787S | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63669870; called by muse, mutect2, varscan2
- SALL1 | c.2938del p.I980Sfs*65 | Frame Shift Del (DEL) | VAF 121/460 reads (26%) | catalogued as COSV99173845; called by mutect2, pindel, varscan2
- SLC9A2 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 251/503 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.258); catalogued as rs200472482, COSV52130363; called by muse, varscan2
- SPAG17 | c.818_820del p.L273del | In Frame Del (DEL) | VAF 198/442 reads (45%) | catalogued as rs747449705; called by pindel, varscan2
- STAB1 | c.1787T>C p.L596P | Missense Mutation (SNP) | VAF 194/480 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1559682287, COSV58741320; called by muse, mutect2, varscan2
- SYNE1 | c.3616G>T p.E1206* (on ENST00000367255 / NM_182961.4; = p.E1213* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 60/453 reads (13%) | catalogued as COSV99549557; called by muse, mutect2, varscan2
- TENM3 | c.7960G>A p.E2654K | Missense Mutation (SNP) | VAF 344/344 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1307412985, COSV69314118; called by muse, mutect2, varscan2
- TM7SF3 | c.1227G>T p.W409C | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58003524; called by muse, mutect2
- TMEM30A | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100034942, COSV57876668; called by muse, mutect2
- TNFRSF14 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 68/467 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as rs770694552, COSV63186373; called by muse, mutect2, varscan2
- USP26 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV63708600; called by muse, mutect2
- ZNF202 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV60247482; called by muse, mutect2
- ZNF208 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs1392709802; called by muse, mutect2
- ACSL4 | c.1354C>T p.R452* (on ENST00000340800 / NM_022977.2; = p.R411* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 463/836 reads (55%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.832A>C p.S278R | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- AP1AR | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APC | c.516del p.P173Lfs*2 | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- ATAD5 | c.2783C>G p.S928C | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ATP10A | c.4257C>A p.S1419R | Missense Mutation (SNP) | VAF 466/466 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ATP6AP2 | c.736A>C p.K246Q | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2
- CARMIL2 | c.3961A>C p.S1321R | Missense Mutation (SNP) | VAF 24/728 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- CIPC | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CTIF | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 44/828 reads (5%) | called by muse, mutect2
- DIAPH2 | c.1268dup p.N423Kfs*16 | Frame Shift Ins (INS) | VAF 42/141 reads (30%) | called by mutect2, pindel, varscan2
- DNAH2 | c.3691C>A p.Q1231K | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2
- DST | c.10174C>T p.Q3392* | Nonsense Mutation (SNP) | VAF 67/219 reads (31%) | called by muse, mutect2, varscan2
- E2F4 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 25/762 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ECT2 | c.2275_2278dup p.P760Qfs*19 (on ENST00000392692 / NM_001349098.2; = p.P729Qfs*19 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 218/366 reads (60%) | called by mutect2, pindel, varscan2
- EPHB6 | c.1085C>A p.P362Q | Missense Mutation (SNP) | VAF 54/1105 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2
- FAM47A | c.2156T>A p.L719H | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.805); called by muse, mutect2
- FASTKD2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 168/448 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FGL2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- FKBPL | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 40/1068 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- HSD3B2 | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 218/517 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IL13RA1 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- IMMT | c.2074T>C p.S692P | Missense Mutation (SNP) | VAF 276/611 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KLRB1 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- KTI12 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 30/529 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.742); called by muse, mutect2
- LPCAT4 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2
- MAP1B | c.660G>T p.L220F | Missense Mutation (SNP) | VAF 60/487 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MSGN1 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 32/631 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- NCAN | c.2335C>A p.Q779K | Missense Mutation (SNP) | VAF 148/900 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PCDH8 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 100/2522 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.024); called by muse, mutect2
- PCDHB12 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 339/472 reads (72%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PEAK3 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 152/901 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEG10 | c.235C>T p.P79S (on ENST00000482108 / NM_001040152.2; = p.P113S on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 473/651 reads (73%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PKNOX2 | c.817-1G>T p.X273_splice | Splice Site (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- PPP1R18 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 649/939 reads (69%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAG1 | c.3995C>T p.P1332L | Missense Mutation (SNP) | VAF 39/1004 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRKD3 | c.2226C>G p.Y742* | Nonsense Mutation (SNP) | VAF 265/481 reads (55%) | called by muse, mutect2, varscan2
- PRSS21 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PTPN4 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 252/471 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- RAB3C | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 20/715 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RANBP1 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 383/657 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RP2 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RSPRY1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- S1PR5 | c.329C>A p.A110E | Missense Mutation (SNP) | VAF 32/1000 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- SCML1 | c.760C>A p.H254N (on ENST00000380041 / NM_001037540.3; = p.H227N on NM_006746.6) | Missense Mutation (SNP) | VAF 27/986 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- SLC19A3 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 34/746 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC19A3 | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 34/748 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SMARCA5 | c.444A>C p.Q148H | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- SOX9 | c.453dup p.R152Afs*100 | Frame Shift Ins (INS) | VAF 232/608 reads (38%) | called by mutect2, pindel, varscan2
- TBC1D21 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 30/337 reads (9%) | called by muse, mutect2
- TGFB2 | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 12/313 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- TMEM14C | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TRPV5 | c.564C>A p.D188E | Missense Mutation (SNP) | VAF 538/732 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.035); called by muse, varscan2
- UBP1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.732); called by muse, mutect2
- USP54 | c.1510A>T p.R504W | Missense Mutation (SNP) | VAF 28/760 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- VPS13B | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2
- WIPI1 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- YAP1 | c.1417A>C p.S473R (on ENST00000282441 / NM_001130145.3; = p.S419R on NM_006106.5) | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2
- ZNF443 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2
- ANK1 | c.4023G>A p.S1341= | Silent (SNP) | VAF 39/728 reads (5%) | catalogued as rs371816885; called by muse, mutect2
- ANKIB1 | c.1722G>C p.V574= | Silent (SNP) | VAF 17/468 reads (4%) | called by muse, mutect2
- CACNA1H | c.1920G>A p.P640= | Silent (SNP) | VAF 252/769 reads (33%) | catalogued as rs370824503; called by muse, mutect2, varscan2
- CCNB3 | c.3337C>A p.R1113= | Silent (SNP) | VAF 143/366 reads (39%) | catalogued as COSV52078579; called by muse, mutect2, varscan2
- CEMIP2 | c.3684G>A p.P1228= | Silent (SNP) | VAF 50/319 reads (16%) | catalogued as rs139406317; called by muse, mutect2, varscan2
- CLTCL1 | c.1992G>T p.V664= | Silent (SNP) | VAF 334/1056 reads (32%) | called by muse, mutect2, varscan2
- CNBD2 | c.340C>T p.L114= | Silent (SNP) | VAF 46/1783 reads (3%) | called by muse, mutect2
- COL4A1 | c.3081G>T p.V1027= | Silent (SNP) | VAF 141/1298 reads (11%) | called by muse, mutect2, varscan2
- INTS3 | c.2559C>T p.S853= | Silent (SNP) | VAF 368/823 reads (45%) | catalogued as rs770825331, COSV99669995; called by muse, varscan2
- KCNJ14 | c.345C>T p.H115= | Silent (SNP) | VAF 580/1051 reads (55%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1584A>G p.A528= | Silent (SNP) | VAF 20/582 reads (3%) | catalogued as COSV56815915; called by muse, mutect2
- KIR2DS4 | c.501C>T p.C167= | Silent (SNP) | VAF 346/746 reads (46%) | catalogued as rs756613837; called by muse, mutect2
- KLF15 | c.699C>T p.G233= | Silent (SNP) | VAF 26/828 reads (3%) | catalogued as rs1490986321; called by muse, mutect2
- KPNB1 | c.2418A>T p.G806= | Silent (SNP) | VAF 15/475 reads (3%) | called by muse, mutect2
- LGALS2 | c.147C>A p.R49= | Silent (SNP) | VAF 34/415 reads (8%) | catalogued as rs755278442; called by muse, mutect2
- MACIR | c.582C>T p.T194= | Silent (SNP) | VAF 306/428 reads (71%) | catalogued as rs782700400; called by muse, mutect2, varscan2
- MYCBP2 | c.9666C>T p.H3222= (on ENST00000357337; = p.H3260= on NM_015057.5) | Silent (SNP) | VAF 169/742 reads (23%) | called by muse, mutect2, varscan2
- NBEAL1 | c.4806C>A p.T1602= | Silent (SNP) | VAF 161/368 reads (44%) | called by muse, mutect2, varscan2
- NID1 | c.3732C>T p.I1244= | Silent (SNP) | VAF 248/537 reads (46%) | catalogued as rs772051661, COSV99937436; called by muse, mutect2
- OASL | c.138G>A p.Q46= | Silent (SNP) | VAF 411/643 reads (64%) | called by muse, mutect2, varscan2
- OR5J2 | c.888C>T p.D296= | Silent (SNP) | VAF 37/315 reads (12%) | catalogued as rs142214796, COSV56620159; called by muse, mutect2, varscan2
- PDIA5 | c.783G>A p.P261= | Silent (SNP) | VAF 34/618 reads (6%) | catalogued as rs777330523; called by muse, mutect2
- RNF128 | c.264G>A p.K88= | Silent (SNP) | VAF 27/672 reads (4%) | catalogued as COSV60946384; called by muse, mutect2
- SMG6 | c.843C>A p.R281= | Silent (SNP) | VAF 459/460 reads (100%) | catalogued as rs1045394839; called by muse, mutect2, varscan2
- SMYD3 | c.942C>T p.S314= (on ENST00000490107 / NM_001375962.1; = p.S255= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 125/477 reads (26%) | called by muse, mutect2, varscan2
- SOGA1 | c.546C>T p.A182= | Silent (SNP) | VAF 502/1827 reads (27%) | called by muse, mutect2, varscan2
- SPEN | c.552C>T p.Y184= | Silent (SNP) | VAF 308/308 reads (100%) | catalogued as rs752587455, COSV65368624; called by muse, mutect2, varscan2
- SPSB4 | c.384C>T p.G128= | Silent (SNP) | VAF 64/1006 reads (6%) | called by muse, mutect2
- SUGP2 | c.1596G>A p.K532= | Silent (SNP) | VAF 259/571 reads (45%) | called by muse, mutect2, varscan2
- TASOR | c.1083A>G p.G361= | Silent (SNP) | VAF 49/126 reads (39%) | called by muse, mutect2, varscan2
- TM6SF1 | c.861G>T p.V287= | Silent (SNP) | VAF 86/171 reads (50%) | called by muse, mutect2, varscan2
- TNRC18 | c.1377C>T p.Y459= | Silent (SNP) | VAF 942/1242 reads (76%) | catalogued as rs767225309; called by muse, mutect2, varscan2
- TTC34 | c.1611C>T p.G537= | Silent (SNP) | VAF 261/520 reads (50%) | called by muse, mutect2, varscan2
- TXLNB | c.1638G>T p.L546= | Silent (SNP) | VAF 244/627 reads (39%) | called by muse, mutect2, varscan2
- VEGFB | c.585C>G p.A195= | Silent (SNP) | VAF 307/842 reads (36%) | catalogued as rs1171687982, COSV58539123; called by muse, mutect2, varscan2
- WDR20 | c.1590G>A p.K530= | Silent (SNP) | VAF 239/240 reads (100%) | catalogued as COSV54470570; called by muse, mutect2, varscan2
- ZNF714 | c.432T>A p.P144= | Silent (SNP) | VAF 59/153 reads (39%) | called by muse, mutect2, varscan2
- FN1 | c.3797-1312T>C | Intron (SNP) | VAF 22/702 reads (3%) | called by muse, mutect2
- HHIP | c.831+28dup | Intron (INS) | VAF 13/154 reads (8%) | called by mutect2, pindel
- MIAT | n.773C>G | RNA (SNP) | VAF 12/314 reads (4%) | catalogued as rs1303453670; called by muse, mutect2
- PCGF3 | c.109+17C>T | Intron (SNP) | VAF 505/506 reads (100%) | catalogued as rs200826324; called by muse, mutect2, varscan2
- SMG7 | c.2742+766G>A | Intron (SNP) | VAF 227/454 reads (50%) | called by muse, mutect2, varscan2
- WDR92 | c.-32T>C | 5'UTR (SNP) | VAF 128/609 reads (21%) | called by muse, mutect2, varscan2
